Gene-level copy-number profile of tumor specimen TCGA-AA-3968-01A from TCGA case TCGA-AA-3968, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 55.0 years (20,089 days).
Specimen TCGA-AA-3968-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.880f57f1-9fd2-407c-98e3-84fa9245f5a8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3968-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/98f24b77-1319-47cc-b58a-6479e4d0ff42

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 1: 581; copy number 2: 22,588; copy number 3: 26,300; copy number 4: 7,784; copy number 5: 842; copy number 6: 1,505; copy number 7: 99; copy number 8: 74.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3968-01A-01D-1018-01): tumor purity 0.71, ploidy 2.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:5,772,926–6,556,555, 11 genes (within-gene range 0–2): AC007846.2, WSCD1, AC104770.1, RNU6-1264P, BTF3P14, AC055872.2, AIPL1, AC055872.1, PIMREG, PITPNM3, Metazoa_SRP.
- chr17:6,600,944–6,601,051, 1 gene: RNA5SP435.
- chr17:11,157,455–12,143,830, 13 genes: RN7SL601P, AC005548.1, SHISA6, AC005725.1, DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1.
- chr17:22,435,390–22,706,703, 19 genes: AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 173 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:23,570,370–24,922,889, 35 genes, copy number 8: TNFRSF19, MIPEP, MTCO3P2, PCOTH, C1QTNF9B, ANKRD20A19P, AL445985.2, AL359736.1, SPATA13, AL445985.1, IPO7P2, MIR2276, SPATA13-AS1, C1QTNF9, C1QTNF9-AS1, AL359736.2, NUS1P3, LINC00566, CYCSP33, TPTE2P6, PARP4, AL359538.4, AL359538.3, PSPC1P2, AL359538.1, AL359538.2, ATP12A, RNY1P7, RPL26P34, AL391560.1, IRX1P1, AL391560.2, ANKRD20A10P, RNF17, CENPJ.
- chr13:24,933,006–24,936,796, 1 gene, copy number 8: AL354798.1.
- chr13:26,557,683–27,989,584, 38 genes, copy number 8: WASF3, RPS3AP44, WASF3-AS1, AL159978.1, GPR12, FGFR1OP2P1, AL160035.1, RPS21P8, RPS20P32, USP12, AL158062.1, USP12-AS1, USP12-AS2, LINC02340, LINC00412, RPL21, SNORD102, SNORA27, RASL11A, RNU6-70P, LINC01079, RNY1P1, GTF3A, MTIF3, RNU6-63P, LNX2, POLR1D, AL136439.1, NPM1P4, GSX1, PLUT, RNU6-73P, PDX1, ATP5F1EP2, LINC00543, CDX2, URAD, RN7SL272P.
- chr17:142,789–2,511,891, 99 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 581. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
